Somatic mutation profile of tumor specimen TCGA-3U-A98D-01A (aliquot TCGA-3U-A98D-01A-12D-A39R-32) from TCGA case TCGA-3U-A98D, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 80.8 years (29,500 days).
Specimen TCGA-3U-A98D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baf22b02-fc65-49a2-8e04-eca809fe06b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98D-10A (Blood Derived Normal), aliquot TCGA-3U-A98D-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ea69066-8348-481c-aa5d-1767dd045c17

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN1 | c.696+1G>A p.X232_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as CS066275, CS121981; called by muse, mutect2, varscan2
- COL19A1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59576312, COSV59586540; called by muse, mutect2, varscan2
- KRTAP10-7 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs369025844, COSV59112099; called by muse, mutect2, varscan2
- NAALADL2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760832134, COSV70795029; called by muse, mutect2, varscan2
- PRRC2C | c.1325A>T p.D442V (on ENST00000367742; = p.D440V on NM_015172.4) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs191833586; called by muse, mutect2, varscan2
- SCN9A | c.5704C>T p.R1902C (on ENST00000303354; = p.R1891C on NM_002977.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs200956485; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBB1 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53888393; called by muse, mutect2, varscan2
- UPK3B | c.599C>T p.A200V (on ENST00000257632; = p.A145V on NM_001347684.2) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1453870331; called by muse, varscan2
- ZBBX | c.1941C>A p.S647R | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1304822753; called by muse, mutect2, varscan2
- ALS2 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- CDH9 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GTSF1 | c.329-2A>G p.X110_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- GUF1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LRRC55 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MAP3K6 | c.3209_3216del p.G1070Afs*65 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- MAPRE1 | c.117C>A p.C39* | Nonsense Mutation (SNP) | VAF 49/155 reads (32%) | called by muse, mutect2, varscan2
- MSH6 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NLRP14 | c.1844T>C p.L615S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NMRK2 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- NOP2 | c.1914del p.K638Nfs*13 (on ENST00000322166 / NM_001258308.2; = p.K634Nfs*13 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- OSGIN2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD51AP2 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- RANBP6 | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- SELENBP1 | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SLC13A4 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.91705G>A p.E30569K (on ENST00000591111; = p.E23145K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | PolyPhen benign (0.124); called by muse, mutect2
- WT1 | c.373_387del p.G125_P129del | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- XPO5 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ACSF2 | c.975C>T p.Y325= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs1355428530, COSV51971920; called by muse, mutect2, varscan2
- AGPAT4 | c.99C>T p.L33= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- AOAH | c.1404G>A p.T468= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs772478951; called by muse, mutect2, varscan2
- CLVS2 | c.822C>T p.S274= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1449797967, COSV51561771, COSV99253622; called by muse, mutect2, varscan2
- DOCK5 | c.4896A>G p.K1632= | Silent (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- FOXS1 | c.408G>A p.A136= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs779625923, COSV99640221; called by muse, mutect2, varscan2
- NRBP1 | c.1062G>A p.E354= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- SULT1B1 | c.879C>T p.R293= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- CDC14B | c.161-1309G>T | Intron (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
